Somatic mutation profile of tumor specimen C3L-04037-03 (aliquot CPT0229540007) from CPTAC case C3L-04037, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 52.0 years (18,998 days).
Specimen C3L-04037-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32bfba47-793e-462a-aae6-8582c4500680.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04037-31 (Blood Derived Normal), aliquot CPT0229680002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a0c9f78-7e5b-43f5-b571-e3bff8f2d595

The open-access MAF lists 507 somatic variants for this specimen: 325 protein-altering or splice-affecting, 100 silent, 82 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 274, Silent 100, Intron 37, RNA 24, Nonsense Mutation 22, Frame Shift Del 17, 5'UTR 10, Splice Site 5, 3'UTR 5, 5'Flank 4, Splice Region 3, 3'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CFTR | c.619C>T p.Q207* | Nonsense Mutation (SNP) | VAF 192/609 reads (32%) | catalogued as rs397508771, CM931143; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.747G>T p.R249S | Missense Mutation (SNP) | VAF 131/223 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs28934571, COSV52661594, COSV52668882, COSV52827572; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- AASS | c.2067G>T p.M689I | Missense Mutation (SNP) | VAF 156/358 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV62790845; called by muse, mutect2, varscan2
- ABCA8 | c.3097G>T p.D1033Y | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV52202660; called by muse, mutect2, varscan2
- ABCD2 | c.1087C>T p.P363S | Missense Mutation (SNP) | VAF 35/88 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58051599, COSV58051996; called by muse, mutect2, varscan2
- ADGB | c.3363C>G p.F1121L | Missense Mutation (SNP) | VAF 51/136 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.281); catalogued as COSV62240593; called by mutect2, varscan2
- ALPK1 | c.1637G>C p.R546P | Missense Mutation (SNP) | VAF 88/140 reads (63%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs757230834; called by muse, mutect2, varscan2
- ANKRD30A | c.548G>T p.R183I (on ENST00000611781; = p.R127I on NM_052997.2) | Missense Mutation (SNP) | VAF 26/73 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as COSV64611285; called by muse, mutect2, varscan2
- ANO1 | c.85G>A p.G29S | Missense Mutation (SNP) | VAF 386/572 reads (67%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs772792209, COSV100797589; called by muse, varscan2
- ARRDC3 | c.1232G>T p.C411F | Missense Mutation (SNP) | VAF 45/107 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as rs573858526; called by muse, mutect2, varscan2
- ATP8B4 | c.1081C>G p.R361G | Missense Mutation (SNP) | VAF 138/351 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.03); catalogued as COSV52714778, COSV99464602; called by muse, mutect2, varscan2
- C2CD4B | c.34G>C p.A12P | Missense Mutation (SNP) | VAF 65/157 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.017); catalogued as COSV100988204; called by muse, mutect2, varscan2
- CAPZA3 | c.565A>G p.I189V | Missense Mutation (SNP) | VAF 121/309 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as rs61740731, COSV56857974; called by muse, mutect2, varscan2
- CCDC96 | c.887A>C p.K296T | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.106); catalogued as COSV100027730; called by muse, mutect2, varscan2
- CCNJL | c.665C>T p.P222L | Missense Mutation (SNP) | VAF 105/259 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV57444080; called by muse, mutect2, varscan2
- CCT4 | c.444G>T p.L148F | Missense Mutation (SNP) | VAF 118/162 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as rs528619072, COSV66702010; called by muse, mutect2, varscan2
- CDH19 | c.454C>A p.P152T | Missense Mutation (SNP) | VAF 74/117 reads (63%) | SIFT tolerated (0.05); PolyPhen benign (0.243); catalogued as COSV50973886; called by muse, mutect2, varscan2
- CHRNA7 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 74/210 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs765144098; called by muse, mutect2, varscan2
- CLPB | c.149T>G p.V50G | Missense Mutation (SNP) | VAF 90/550 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.015); catalogued as COSV53629470; called by muse, mutect2, varscan2
- COL18A1 | c.2765G>A p.R922H (on ENST00000359759 / NM_130444.3; = p.R687H on NM_030582.4) | Missense Mutation (SNP) | VAF 233/659 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs775248850, COSV100700634; called by muse, mutect2, varscan2
- COL22A1 | c.1576C>A p.Q526K | Missense Mutation (SNP) | VAF 55/177 reads (31%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as COSV57332061; called by muse, mutect2, varscan2
- CYP11B1 | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 94/321 reads (29%) | catalogued as COSV52830673; called by muse, mutect2, varscan2
- CYP11B1 | c.1110G>T p.K370N | Missense Mutation (SNP) | VAF 91/318 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99455644; called by muse, mutect2, varscan2
- DLEC1 | c.2664G>C p.Q888H | Missense Mutation (SNP) | VAF 135/239 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV57300015; called by muse, mutect2, varscan2
- DYNC2H1 | c.7943G>T p.G2648V | Missense Mutation (SNP) | VAF 102/946 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1304742519; called by muse, mutect2, varscan2
- EPB42 | c.1090G>T p.D364Y (on ENST00000441366 / NM_001114134.2; = p.D394Y on NM_000119.3) | Missense Mutation (SNP) | VAF 163/441 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.656); catalogued as rs1195604855, COSV55749086; called by muse, mutect2, varscan2
- EPHB1 | c.2908C>A p.H970N | Missense Mutation (SNP) | VAF 78/253 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.02); catalogued as COSV67674983; called by muse, mutect2, varscan2
- ERBB4 | c.1818G>T p.K606N | Missense Mutation (SNP) | VAF 367/489 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV53558198; called by muse, mutect2, varscan2
- ERICH3 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 71/203 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1159893217, COSV58618484; called by muse, mutect2, varscan2
- ESR2 | c.1036C>A p.R346S | Missense Mutation (SNP) | VAF 73/261 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50835079; called by muse, mutect2, varscan2
- F13A1 | c.1547G>T p.R516M | Missense Mutation (SNP) | VAF 177/490 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV99342117; called by muse, mutect2, varscan2
- FLAD1 | c.1670C>T p.P557L | Missense Mutation (SNP) | VAF 259/545 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.591); catalogued as rs974386360; called by muse, mutect2, varscan2
- FLG2 | c.4736C>G p.S1579C | Missense Mutation (SNP) | VAF 108/477 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV101166196; called by muse, mutect2, varscan2
- FSIP2 | c.20621C>A p.S6874Y | Missense Mutation (SNP) | VAF 116/152 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV58103499; called by muse, mutect2, varscan2
- GABRG1 | c.722T>A p.V241E | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV99778407; called by muse, varscan2
- GIGYF1 | c.214G>C p.E72Q | Missense Mutation (SNP) | VAF 72/241 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99310174; called by muse, mutect2, varscan2
- GLYAT | c.890G>T p.*297Lext*4 | Nonstop Mutation (SNP) | VAF 32/74 reads (43%) | catalogued as COSV53540215; called by muse, mutect2, varscan2
- GPR83 | c.441C>G p.S147R | Missense Mutation (SNP) | VAF 273/373 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54718437; called by muse, mutect2, varscan2
- GRIK3 | c.1355C>A p.S452* | Nonsense Mutation (SNP) | VAF 137/227 reads (60%) | catalogued as COSV66138417; called by muse, mutect2, varscan2
- HMCES | c.377A>G p.Y126C | Missense Mutation (SNP) | VAF 83/250 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs753745495; called by muse, mutect2, varscan2
- HR | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 103/160 reads (64%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1199237644; called by muse, mutect2, varscan2
- IL2RB | c.502G>A p.E168K | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs761376327; called by muse, mutect2
- INSYN2B | c.1366G>C p.G456R | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56987005; called by muse, varscan2
- ITPR2 | c.2287C>T p.R763W | Missense Mutation (SNP) | VAF 181/516 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs1254629109, COSV67270853; called by muse, mutect2, varscan2
- KCNK10 | c.1418A>G p.Y473C | Missense Mutation (SNP) | VAF 208/588 reads (35%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.533); catalogued as COSV100069405; called by muse, mutect2, varscan2
- KLRC1 | c.311C>A p.S104Y | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.367); catalogued as rs867786860, COSV100760723; called by muse, mutect2, varscan2
- KMT2B | c.3905G>T p.R1302L | Missense Mutation (SNP) | VAF 121/190 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs771289674; called by muse, mutect2, varscan2
- KRIT1 | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 143/383 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1161802228; called by muse, mutect2, varscan2
- MAP4K4 | c.1704+6C>T | Splice Region (SNP) | VAF 240/303 reads (79%) | catalogued as rs371096311; called by muse, mutect2, varscan2
- MFN2 | c.982G>C p.A328P | Missense Mutation (SNP) | VAF 193/325 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); catalogued as COSV99336686; called by muse, mutect2, varscan2
- MOV10L1 | c.2083A>G p.M695V | Missense Mutation (SNP) | VAF 49/79 reads (62%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs144190475; called by muse, mutect2, varscan2
- MSH4 | c.2039G>T p.G680V | Missense Mutation (SNP) | VAF 67/161 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54203185; called by muse, mutect2, varscan2
- MUC17 | c.9759G>C p.L3253F | Missense Mutation (SNP) | VAF 81/245 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.626); catalogued as rs776001776, COSV60288504; called by muse, mutect2, varscan2
- MXD3 | c.598C>A p.H200N | Missense Mutation (SNP) | VAF 102/276 reads (37%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100293411; called by muse, mutect2, varscan2
- MXRA5 | c.3473G>T p.R1158L | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV54237183; called by muse, mutect2, varscan2
- NFKBIL1 | c.911G>A p.C304Y | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs1192553202; called by muse, mutect2, varscan2
- NKIRAS2 | c.157del p.V53Cfs*78 | Frame Shift Del (DEL) | VAF 15/68 reads (22%) | catalogued as COSV100288809; called by mutect2, pindel
- NT5C1A | c.947C>G p.P316R | Missense Mutation (SNP) | VAF 91/137 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1385072618; called by muse, mutect2, varscan2
- OLFM3 | c.1352G>T p.R451L (on ENST00000338858 / NM_001288821.1; = p.R431L on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV58806161; called by muse, mutect2, varscan2
- OR2L2 | c.891G>T p.M297I | Missense Mutation (SNP) | VAF 100/195 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs891670996, COSV100824225, COSV63561835; called by muse, mutect2, varscan2
- OR2M5 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 173/377 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.452); catalogued as COSV100822754; called by muse, mutect2, varscan2
- OR2T33 | c.591G>T p.M197I | Missense Mutation (SNP) | VAF 174/991 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.242); catalogued as rs748323044; called by muse, varscan2
- OR56A1 | c.726C>G p.S242R | Missense Mutation (SNP) | VAF 75/153 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as rs376891340; called by muse, mutect2, varscan2
- OR8H3 | c.806G>C p.G269A | Missense Mutation (SNP) | VAF 61/171 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs144272907; called by muse, mutect2, varscan2
- OTOGL | c.6439del p.E2147Kfs*11 (on ENST00000547103; = p.E2138Kfs*11 on NM_173591.4 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 16/48 reads (33%) | catalogued as COSV54016960; called by mutect2, pindel
- PAPOLB | c.1431G>T p.M477I | Missense Mutation (SNP) | VAF 215/407 reads (53%) | SIFT tolerated (0.21); PolyPhen benign (0.026); catalogued as rs918742845; called by muse, mutect2, varscan2
- PCDHB2 | c.1862C>T p.A621V | Missense Mutation (SNP) | VAF 283/892 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.409); catalogued as rs1554271580; called by muse, mutect2, varscan2
- PCDHB3 | c.2145G>T p.R715S | Missense Mutation (SNP) | VAF 165/437 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.786); catalogued as COSV99164071; called by muse, mutect2, varscan2
- PCDHGA2 | c.1385C>A p.P462H | Missense Mutation (SNP) | VAF 119/300 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV53949523; called by muse, mutect2, varscan2
- PCLO | c.13469A>G p.Y4490C | Missense Mutation (SNP) | VAF 80/222 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61653380; called by muse, mutect2, varscan2
- PCLO | c.2881G>T p.G961W | Missense Mutation (SNP) | VAF 87/219 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.91); catalogued as COSV61625856, COSV61677168; called by muse, mutect2, varscan2
- PDCD10 | c.373G>C p.V125L | Missense Mutation (SNP) | VAF 116/317 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as CD135554; called by muse, mutect2, varscan2
- PKDREJ | c.4765A>G p.S1589G | Missense Mutation (SNP) | VAF 79/140 reads (56%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1490126853; called by muse, mutect2, varscan2
- PSKH2 | c.416T>G p.L139R | Missense Mutation (SNP) | VAF 117/332 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52611939; called by muse, mutect2, varscan2
- PTPRD | c.2017del p.L673Ffs*15 | Frame Shift Del (DEL) | VAF 171/362 reads (47%) | catalogued as COSV61976061; called by mutect2, pindel, varscan2
- QTRT2 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 85/314 reads (27%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.837); catalogued as rs1553760139; called by muse, mutect2, varscan2
- RAET1G | c.260G>A p.W87* | Nonsense Mutation (SNP) | VAF 92/1088 reads (8%) | catalogued as rs1285904058, COSV66273940, COSV66274958; called by muse, mutect2
- ROS1 | c.6646C>G p.Q2216E | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV63862157; called by muse, mutect2, varscan2
- RTKN | c.1183_1184del p.T395Pfs*22 (on ENST00000272430 / NM_001015055.2; = p.T382Pfs*22 on NM_033046.2) | Frame Shift Del (DEL) | VAF 56/232 reads (24%) | catalogued as rs1229305845; called by pindel, varscan2
- RYR2 | c.13618G>A p.E4540K | Missense Mutation (SNP) | VAF 119/377 reads (32%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.5); catalogued as COSV100772266; called by muse, mutect2, varscan2
- SCRN3 | c.482G>A p.R161K | Missense Mutation (SNP) | VAF 98/324 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as rs772684562; called by muse, mutect2, varscan2
- SIAH3 | c.468G>T p.W156C | Missense Mutation (SNP) | VAF 546/687 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771148880; called by muse, mutect2, varscan2
- SIGLEC8 | c.887C>T p.T296I | Missense Mutation (SNP) | VAF 173/266 reads (65%) | SIFT tolerated (0.11); PolyPhen benign (0.221); catalogued as COSV58471768; called by muse, mutect2, varscan2
- SLC9A6 | c.1314G>C p.L438F | Missense Mutation (SNP) | VAF 100/129 reads (78%) | SIFT deleterious (0.04); PolyPhen benign (0.16); catalogued as COSV100857936; called by muse, mutect2, varscan2
- SLCO1B1 | c.1123A>G p.N375D | Missense Mutation (SNP) | VAF 34/137 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1463981909; called by muse, mutect2, varscan2
- SLCO3A1 | c.71A>G p.Q24R | Missense Mutation (SNP) | VAF 48/140 reads (34%) | SIFT tolerated (0.94); PolyPhen benign (0.029); catalogued as rs1255689700; called by muse, mutect2, varscan2
- SORCS1 | c.209T>A p.L70Q | Missense Mutation (SNP) | VAF 36/88 reads (41%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.009); catalogued as COSV53859191; called by muse, mutect2, varscan2
- SPHKAP | c.970C>T p.H324Y | Missense Mutation (SNP) | VAF 153/229 reads (67%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60884498; called by muse, mutect2, varscan2
- TFCP2L1 | c.1383C>A p.S461R | Missense Mutation (SNP) | VAF 135/167 reads (81%) | SIFT tolerated (0.28); PolyPhen benign (0.014); catalogued as rs377179811, COSV55294253; called by muse, mutect2, varscan2
- TMPRSS15 | c.1780G>A p.A594T | Missense Mutation (SNP) | VAF 66/207 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as rs754255036, COSV99518764; called by muse, mutect2, varscan2
- TNIK | c.1633C>T p.R545W | Missense Mutation (SNP) | VAF 46/129 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs200431570; called by muse, mutect2, varscan2
- TNRC6A | c.3766G>T p.G1256W | Missense Mutation (SNP) | VAF 101/286 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100170274; called by muse, varscan2
- TRIM3 | c.595G>T p.A199S | Missense Mutation (SNP) | VAF 109/359 reads (30%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs760883267; called by muse, mutect2, varscan2
- TRPM5 | c.2194G>T p.V732L | Missense Mutation (SNP) | VAF 156/453 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as COSV50176685; called by muse, mutect2, varscan2
- UBE2D2 | c.269G>A p.R90Q | Missense Mutation (SNP) | VAF 44/133 reads (33%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.08); catalogued as COSV54081074; called by muse, mutect2, varscan2
- UIMC1 | c.1913-1G>A p.X638_splice | Splice Site (SNP) | VAF 61/172 reads (35%) | catalogued as rs1164776265; called by muse, mutect2, varscan2
- USH2A | c.256C>G p.Q86E | Missense Mutation (SNP) | VAF 95/284 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV56410172; called by muse, mutect2, varscan2
- VNN3 | c.366A>T p.Q122H | Missense Mutation (SNP) | VAF 53/144 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs771641620; called by muse, mutect2, varscan2
- ZIC4 | c.236C>A p.P79Q | Missense Mutation (SNP) | VAF 50/133 reads (38%) | SIFT tolerated (0.63); PolyPhen benign (0.045); catalogued as rs755472014, COSV101267810, COSV101268230; called by muse, mutect2, varscan2
- ABCA1 | c.1087G>C p.E363Q | Missense Mutation (SNP) | VAF 114/194 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- AC098582.1 | c.1222G>A p.A408T | Missense Mutation (SNP) | VAF 47/85 reads (55%) | SIFT tolerated (0.55); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- ACE | c.830T>C p.I277T | Missense Mutation (SNP) | VAF 102/321 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by mutect2, varscan2
- ACSM4 | c.144G>T p.L48F | Missense Mutation (SNP) | VAF 116/367 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- ACSM5 | c.592C>T p.P198S | Missense Mutation (SNP) | VAF 220/581 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ADAMTS17 | c.2666T>C p.V889A | Missense Mutation (SNP) | VAF 229/666 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- ADAMTS19 | c.3050C>A p.T1017K | Missense Mutation (SNP) | VAF 163/275 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.339); called by muse, mutect2, varscan2
- ADAMTS19 | c.3448A>T p.N1150Y | Missense Mutation (SNP) | VAF 59/88 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADD2 | c.663C>A p.D221E | Missense Mutation (SNP) | VAF 124/155 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ADGB | c.301A>T p.K101* | Nonsense Mutation (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- ADGRL3 | c.3239G>T p.C1080F (on ENST00000506720 / NM_001322402.2; = p.C1012F on NM_015236.6) | Missense Mutation (SNP) | VAF 25/47 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- AKAP9 | c.652A>T p.R218* | Nonsense Mutation (SNP) | VAF 83/249 reads (33%) | called by muse, mutect2, varscan2
- ALG6 | c.493C>T p.Q165* | Nonsense Mutation (SNP) | VAF 81/250 reads (32%) | called by muse, mutect2, varscan2
- AOC3 | c.1072A>G p.R358G | Missense Mutation (SNP) | VAF 222/588 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- AP2B1 | c.205G>T p.V69L | Missense Mutation (SNP) | VAF 45/185 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- APBA2 | c.1686C>A p.N562K | Missense Mutation (SNP) | VAF 231/619 reads (37%) | SIFT tolerated (0.64); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- ARMC3 | c.666G>T p.K222N | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- ATP10A | c.2329C>T p.Q777* | Nonsense Mutation (SNP) | VAF 153/394 reads (39%) | called by muse, mutect2, varscan2
- ATP2B4 | c.3050A>T p.K1017I | Missense Mutation (SNP) | VAF 50/151 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- ATXN7L2 | c.1985G>T p.C662F | Missense Mutation (SNP) | VAF 99/276 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.896); called by muse, varscan2
- B3GALT1 | c.895del p.R299Efs*42 | Frame Shift Del (DEL) | VAF 70/129 reads (54%) | called by mutect2, pindel, varscan2
- BRINP3 | c.1727T>A p.F576Y | Missense Mutation (SNP) | VAF 163/307 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- BRWD3 | c.2749G>T p.E917* | Nonsense Mutation (SNP) | VAF 45/60 reads (75%) | called by muse, mutect2, varscan2
- BTBD8 | c.1408G>T p.D470Y | Missense Mutation (SNP) | VAF 82/239 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- C16orf96 | c.3049G>T p.V1017L | Missense Mutation (SNP) | VAF 116/334 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- C5orf52 | c.100G>T p.G34C | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- CALN1 | c.533T>A p.V178E (on ENST00000329008 / NM_001017440.3; = p.V220E on NM_031468.4) | Missense Mutation (SNP) | VAF 76/188 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC39 | c.2805G>C p.K935N | Missense Mutation (SNP) | VAF 88/246 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- CD2AP | c.230A>T p.N77I | Missense Mutation (SNP) | VAF 128/342 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CDC25B | c.664G>A p.E222K (on ENST00000245960 / NM_021873.3; = p.E208K on NM_004358.4) | Missense Mutation (SNP) | VAF 112/194 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- CDC42EP3 | c.502G>T p.G168* | Nonsense Mutation (SNP) | VAF 185/239 reads (77%) | called by muse, mutect2, varscan2
- CDH12 | c.785T>C p.V262A | Missense Mutation (SNP) | VAF 51/151 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CDRT1 | c.1911C>G p.I637M | Missense Mutation (SNP) | VAF 94/159 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CEP70 | c.465+1G>A p.X155_splice | Splice Site (SNP) | VAF 22/65 reads (34%) | called by muse, mutect2, varscan2
- CFHR5 | c.1493C>G p.S498* | Nonsense Mutation (SNP) | VAF 138/507 reads (27%) | called by muse, mutect2, varscan2
- COL5A2 | c.1474G>T p.G492C | Missense Mutation (SNP) | VAF 270/354 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL5A2 | c.1473G>T p.Q491H | Missense Mutation (SNP) | VAF 266/353 reads (75%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- COL9A1 | c.1926G>T p.L642= | Splice Region (SNP) | VAF 158/434 reads (36%) | called by muse, mutect2, varscan2
- COPA | c.3299del p.H1100Pfs*2 | Frame Shift Del (DEL) | VAF 126/281 reads (45%) | called by mutect2, pindel, varscan2
- CPM | c.888T>A p.F296L | Missense Mutation (SNP) | VAF 76/257 reads (30%) | SIFT tolerated (0.31); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- CRTC2 | c.1980G>A p.M660I | Missense Mutation (SNP) | VAF 332/1074 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- CSMD3 | c.6090A>T p.Q2030H (on ENST00000297405 / NM_001363185.1; = p.Q1926H on NM_052900.3) | Missense Mutation (SNP) | VAF 66/190 reads (35%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- CTTNBP2NL | c.1639A>T p.S547C | Missense Mutation (SNP) | VAF 115/303 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CUBN | c.10799A>G p.N3600S | Missense Mutation (SNP) | VAF 188/576 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CXCR3 | c.323T>G p.L108R | Missense Mutation (SNP) | VAF 68/102 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CYLC1 | c.1180G>T p.D394Y | Missense Mutation (SNP) | VAF 59/86 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.865); called by muse, mutect2, varscan2
- CYP2B6 | c.587T>A p.L196Q | Missense Mutation (SNP) | VAF 97/152 reads (64%) | SIFT tolerated (0.09); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- CYP2C19 | c.1129A>G p.R377G | Missense Mutation (SNP) | VAF 117/286 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- DACT1 | c.221G>C p.R74P | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DCST2 | c.1594_1596del p.Y532del | In Frame Del (DEL) | VAF 170/344 reads (49%) | called by pindel, varscan2
- DGKB | c.1733T>A p.V578E | Missense Mutation (SNP) | VAF 169/309 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- DGKB | c.1732G>A p.V578M | Missense Mutation (SNP) | VAF 173/315 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- DMP1 | c.313G>C p.D105H | Missense Mutation (SNP) | VAF 76/123 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJC5B | c.254C>A p.S85* | Nonsense Mutation (SNP) | VAF 198/512 reads (39%) | called by muse, mutect2, varscan2
- ELP4 | c.1016A>T p.N339I (on ENST00000350638; = p.N338I on NM_019040.5) | Missense Mutation (SNP) | VAF 48/138 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- EML4 | c.1870C>A p.H624N | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- EP400 | c.8631G>T p.L2877F | Missense Mutation (SNP) | VAF 161/428 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.148); called by muse, mutect2, varscan2
- ERICH3 | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 66/173 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- F7 | c.1353G>T p.M451I | Missense Mutation (SNP) | VAF 203/278 reads (73%) | SIFT deleterious (0.01); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- FAM135B | c.4092C>A p.H1364Q | Missense Mutation (SNP) | VAF 206/572 reads (36%) | SIFT tolerated (0.24); PolyPhen benign (0.24); called by muse, mutect2, varscan2
- FAM135B | c.3691C>A p.P1231T | Missense Mutation (SNP) | VAF 116/349 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FANCB | c.2252G>T p.S751I | Missense Mutation (SNP) | VAF 27/40 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- FAT3 | c.1918A>T p.T640S | Missense Mutation (SNP) | VAF 305/388 reads (79%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FBN3 | c.2991C>A p.C997* | Nonsense Mutation (SNP) | VAF 124/205 reads (60%) | called by muse, mutect2, varscan2
- FBRSL1 | c.2494G>T p.A832S | Missense Mutation (SNP) | VAF 39/126 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- FHL5 | c.677C>A p.S226Y | Missense Mutation (SNP) | VAF 41/111 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- FRG2C | c.659C>A p.A220D | Missense Mutation (SNP) | VAF 151/667 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GALNT13 | c.874G>C p.G292R | Missense Mutation (SNP) | VAF 112/162 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GAPVD1 | c.689A>T p.Q230L | Missense Mutation (SNP) | VAF 99/161 reads (61%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GH2 | c.427C>A p.L143I | Missense Mutation (SNP) | VAF 145/370 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GIMAP4 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 61/194 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- GIMAP4 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 62/195 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- GK3P | c.1125C>A p.S375R | Missense Mutation (SNP) | VAF 149/250 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- GLI3 | c.3486G>T p.W1162C | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GLYATL1 | c.697T>G p.Y233D (on ENST00000317391 / NM_001354699.1; = p.Y264D on NM_080661.4) | Missense Mutation (SNP) | VAF 190/485 reads (39%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GP2 | c.521T>G p.L174R | Missense Mutation (SNP) | VAF 38/109 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, varscan2
- GPR4 | c.167T>A p.L56Q | Missense Mutation (SNP) | VAF 65/107 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIK3 | c.2433A>T p.K811N | Missense Mutation (SNP) | VAF 142/254 reads (56%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.686); called by muse, mutect2, varscan2
- GRIN1 | c.701C>T p.A234V | Missense Mutation (SNP) | VAF 132/226 reads (58%) | SIFT tolerated (0.3); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- HAVCR1 | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- HCN1 | c.2651C>A p.P884Q | Missense Mutation (SNP) | VAF 171/495 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.271); called by muse, varscan2
- HCN1 | c.2650C>A p.P884T | Missense Mutation (SNP) | VAF 169/493 reads (34%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.038); called by muse, varscan2
- HDGFL1 | c.623G>C p.S208T | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- HDX | c.1987G>T p.D663Y | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- HECW2 | c.4328C>A p.A1443E | Missense Mutation (SNP) | VAF 162/229 reads (71%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- HK3 | c.2628-2A>T p.X876_splice | Splice Site (SNP) | VAF 144/417 reads (35%) | called by muse, mutect2, varscan2
- HOXA3 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- HRG | c.922C>T p.H308Y | Missense Mutation (SNP) | VAF 123/327 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- IL21R | c.1053C>G p.F351L | Missense Mutation (SNP) | VAF 105/291 reads (36%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INTS1 | c.6482G>T p.R2161L | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- KALRN | c.1525G>T p.D509Y | Missense Mutation (SNP) | VAF 127/445 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KBTBD13 | c.55del p.Q19Kfs*35 | Frame Shift Del (DEL) | VAF 48/129 reads (37%) | called by mutect2, pindel, varscan2
- KCMF1 | c.524G>T p.S175I | Missense Mutation (SNP) | VAF 176/227 reads (78%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- KCNC2 | c.1844C>A p.S615Y | Missense Mutation (SNP) | VAF 94/264 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- KCNH1 | c.1871G>T p.G624V (on ENST00000271751 / NM_172362.3; = p.G597V on NM_002238.4) | Missense Mutation (SNP) | VAF 120/394 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNH1 | c.1870G>T p.G624C (on ENST00000271751 / NM_172362.3; = p.G597C on NM_002238.4) | Missense Mutation (SNP) | VAF 122/398 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KHDC1L | c.322A>T p.S108C | Missense Mutation (SNP) | VAF 58/189 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- KIF4B | c.1171A>T p.K391* | Nonsense Mutation (SNP) | VAF 210/541 reads (39%) | called by muse, mutect2, varscan2
- KLHL4 | c.1069G>T p.V357L | Missense Mutation (SNP) | VAF 66/85 reads (78%) | SIFT tolerated (0.88); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KLK14 | c.115C>A p.Q39K | Missense Mutation (SNP) | VAF 80/133 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLKB1 | c.355G>T p.V119F | Missense Mutation (SNP) | VAF 132/220 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- KRT78 | c.911A>G p.Y304C | Missense Mutation (SNP) | VAF 38/130 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- KRT86 | c.20G>T p.C7F | Missense Mutation (SNP) | VAF 583/1079 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LAMA2 | c.6907A>T p.M2303L | Missense Mutation (SNP) | VAF 152/406 reads (37%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- LEUTX | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- LSAMP | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- MAB21L3 | c.828G>T p.R276S | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- MCF2 | c.2632G>T p.V878F | Missense Mutation (SNP) | VAF 51/66 reads (77%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.514); called by muse, mutect2, varscan2
- MCTP1 | c.1709A>T p.Q570L | Missense Mutation (SNP) | VAF 50/67 reads (75%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- MCTP1 | c.1707G>T p.L569F | Missense Mutation (SNP) | VAF 51/67 reads (76%) | SIFT deleterious (0.02); PolyPhen benign (0.261); called by muse, mutect2
- MMP19 | c.1039C>A p.Q347K | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MOB2 | c.97A>T p.T33S | Missense Mutation (SNP) | VAF 156/412 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MROH2B | c.890T>C p.M297T | Missense Mutation (SNP) | VAF 43/113 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTRNR2L5 | c.63G>T p.K21N | Missense Mutation (SNP) | VAF 29/103 reads (28%) | PolyPhen possibly damaging (0.617); called by muse, mutect2, varscan2
- MUC12 | c.3404C>T p.T1135I (on ENST00000379442; = p.T992I on NM_001164462.1) | Missense Mutation (SNP) | VAF 397/549 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- MUC5AC | c.14669G>T p.R4890M | Missense Mutation (SNP) | VAF 123/426 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- MVK | c.214del p.T72Qfs*20 | Frame Shift Del (DEL) | VAF 185/582 reads (32%) | called by mutect2, pindel, varscan2
- MYO18B | c.1192C>A p.P398T | Missense Mutation (SNP) | VAF 97/163 reads (60%) | SIFT deleterious (0.04); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- MYOCD | c.2272C>A p.H758N | Missense Mutation (SNP) | VAF 41/70 reads (59%) | SIFT tolerated (0.07); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- MYPN | c.1273G>T p.G425* | Nonsense Mutation (SNP) | VAF 228/589 reads (39%) | called by muse, mutect2, varscan2
- MYT1L | c.2422C>A p.Q808K | Missense Mutation (SNP) | VAF 177/239 reads (74%) | SIFT tolerated (0.09); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- NEBL | c.239T>C p.L80S | Missense Mutation (SNP) | VAF 184/479 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NELL1 | c.2062A>T p.T688S | Missense Mutation (SNP) | VAF 69/251 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.182); called by muse, mutect2, varscan2
- NEURL1 | c.603G>T p.W201C | Missense Mutation (SNP) | VAF 64/175 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- NIPAL2 | c.879A>T p.A293= | Splice Region (SNP) | VAF 64/134 reads (48%) | called by muse, mutect2, varscan2
- NLGN1 | c.2375A>T p.Q792L | Missense Mutation (SNP) | VAF 102/272 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.209); called by muse, mutect2, varscan2
- NLRC5 | c.3653G>T p.C1218F | Missense Mutation (SNP) | VAF 159/240 reads (66%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- NOX3 | c.1417A>G p.S473G | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- NPAP1 | c.1246T>A p.Y416N | Missense Mutation (SNP) | VAF 60/196 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- NPC1L1 | c.1209del p.F404Sfs*7 | Frame Shift Del (DEL) | VAF 253/1129 reads (22%) | called by mutect2, pindel, varscan2
- NPY5R | c.18C>A p.D6E | Missense Mutation (SNP) | VAF 13/22 reads (59%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRXN3 | c.1919C>A p.S640* (on ENST00000335750 / NM_001330195.2; = p.S267* on NM_004796.6) | Nonsense Mutation (SNP) | VAF 134/346 reads (39%) | called by muse, mutect2, varscan2
- NUP205 | c.3732G>T p.Q1244H | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NUP98 | c.535A>G p.S179G | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.4); called by muse, mutect2, varscan2
- OLFML2A | c.634G>T p.A212S | Missense Mutation (SNP) | VAF 72/119 reads (61%) | SIFT tolerated (0.55); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR10Q1 | c.241G>T p.V81L | Missense Mutation (SNP) | VAF 115/302 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OR13A1 | c.164G>T p.G55V | Missense Mutation (SNP) | VAF 123/319 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR2L5 | c.485C>G p.A162G | Missense Mutation (SNP) | VAF 168/608 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.048); called by muse, mutect2, varscan2
- OR2T4 | c.963C>G p.I321M | Missense Mutation (SNP) | VAF 206/765 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- OR2T8 | c.591G>T p.M197I | Missense Mutation (SNP) | VAF 20/164 reads (12%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.497); called by mutect2, varscan2
- OR4C15 | c.279del p.N94Tfs*3 (on ENST00000314644; = p.N40Tfs*3 on NM_001001920.2) | Frame Shift Del (DEL) | VAF 118/400 reads (30%) | called by mutect2, pindel, varscan2
- OR52M1 | c.556G>T p.A186S | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OTOGL | c.2303C>A p.P768Q (on ENST00000547103; = p.P759Q on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 94/305 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.056); called by muse, mutect2
- PAPPA2 | c.946G>C p.V316L | Missense Mutation (SNP) | VAF 82/256 reads (32%) | SIFT tolerated (0.78); PolyPhen benign (0.003); called by muse, mutect2
- PAPPA2 | c.1783del p.H595Ifs*42 | Frame Shift Del (DEL) | VAF 92/376 reads (24%) | called by mutect2, pindel, varscan2
- PARD3B | c.2657G>T p.G886V (on ENST00000406610 / NM_001302769.2; = p.G817V on NM_057177.7) | Missense Mutation (SNP) | VAF 212/285 reads (74%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PATJ | c.3703G>T p.G1235* | Nonsense Mutation (SNP) | VAF 63/209 reads (30%) | called by muse, mutect2, varscan2
- PCDH11Y | c.3247G>T p.G1083C | Missense Mutation (SNP) | VAF 229/311 reads (74%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- PCDH12 | c.2160C>G p.I720M | Missense Mutation (SNP) | VAF 96/253 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PCDH17 | c.3155G>T p.G1052V | Missense Mutation (SNP) | VAF 210/272 reads (77%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- PCDHA1 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 147/412 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA12 | c.206A>G p.K69R | Missense Mutation (SNP) | VAF 256/858 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.031); called by muse, varscan2
- PCDHB3 | c.2144G>T p.R715M | Missense Mutation (SNP) | VAF 158/399 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); called by mutect2, varscan2
- PCDHGA3 | c.2029A>G p.S677G | Missense Mutation (SNP) | VAF 177/440 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.039); called by mutect2, varscan2
- PCNX3 | c.4603G>A p.D1535N | Missense Mutation (SNP) | VAF 909/1321 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- PDILT | c.850A>G p.K284E | Missense Mutation (SNP) | VAF 84/172 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- PHACTR2 | c.946A>T p.N316Y | Missense Mutation (SNP) | VAF 118/316 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); called by muse, mutect2, varscan2
- PHF7 | c.517G>C p.E173Q | Missense Mutation (SNP) | VAF 44/56 reads (79%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- PLCL1 | c.235A>G p.I79V | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PPP1R16B | c.1028+1del | Frame Shift Del (DEL) | VAF 113/198 reads (57%) | called by mutect2, pindel, varscan2
- PRDM10 | c.3422A>T p.Y1141F | Missense Mutation (SNP) | VAF 112/177 reads (63%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRDM9 | c.441G>T p.Q147H | Missense Mutation (SNP) | VAF 91/279 reads (33%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PREX2 | c.1643-2A>C p.X548_splice | Splice Site (SNP) | VAF 76/222 reads (34%) | called by muse, mutect2, varscan2
- PRLHR | c.1100G>T p.S367I | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.314); called by muse, varscan2
- PTPRO | c.2072T>C p.L691P | Missense Mutation (SNP) | VAF 201/495 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- RAET1L | c.260G>A p.W87* | Nonsense Mutation (SNP) | VAF 81/158 reads (51%) | called by muse, mutect2, varscan2
- RANBP2 | c.8166G>C p.E2722D | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM12B | c.1834A>T p.R612W | Missense Mutation (SNP) | VAF 96/214 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- RELN | c.7553T>C p.L2518P | Missense Mutation (SNP) | VAF 183/463 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RFPL4B | c.487T>C p.C163R | Missense Mutation (SNP) | VAF 171/433 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RGP1 | c.63G>C p.E21D | Missense Mutation (SNP) | VAF 108/168 reads (64%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- RGS9 | c.520A>G p.K174E | Missense Mutation (SNP) | VAF 155/525 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RGSL1 | c.2657C>G p.S886C | Missense Mutation (SNP) | VAF 63/111 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- RIOX2 | c.277G>T p.G93W | Missense Mutation (SNP) | VAF 143/455 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- RNF113B | c.39dup p.A14Sfs*75 | Frame Shift Ins (INS) | VAF 67/114 reads (59%) | called by mutect2, pindel, varscan2
- RNF213 | c.11210A>C p.K3737T | Missense Mutation (SNP) | VAF 195/552 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- ROR1 | c.2213G>C p.R738T | Missense Mutation (SNP) | VAF 80/225 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- RPGRIP1 | c.2744C>G p.P915R | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- RPUSD2 | c.802C>A p.H268N | Missense Mutation (SNP) | VAF 156/433 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); called by muse, mutect2, varscan2
- RYR3 | c.2414G>C p.G805A | Missense Mutation (SNP) | VAF 114/337 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- S1PR1 | c.1073C>A p.S358Y | Missense Mutation (SNP) | VAF 102/257 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2, varscan2
- SCARF2 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 149/255 reads (58%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- SCN3A | c.5390G>A p.W1797* | Nonsense Mutation (SNP) | VAF 297/388 reads (77%) | called by muse, mutect2, varscan2
- SDK2 | c.2377G>C p.V793L | Missense Mutation (SNP) | VAF 77/187 reads (41%) | SIFT tolerated (0.06); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- SEMA6B | c.1897C>G p.R633G | Missense Mutation (SNP) | VAF 117/178 reads (66%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- SLC17A7 | c.435-2A>T p.X145_splice | Splice Site (SNP) | VAF 88/145 reads (61%) | called by muse, mutect2, varscan2
- SLC27A6 | c.361G>T p.V121L | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.45); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- SLC2A12 | c.1600T>C p.Y534H | Missense Mutation (SNP) | VAF 100/235 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SMG7 | c.476G>C p.G159A | Missense Mutation (SNP) | VAF 47/128 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SND1 | c.1340G>C p.G447A | Missense Mutation (SNP) | VAF 78/190 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- SORCS1 | c.2084A>T p.K695I | Missense Mutation (SNP) | VAF 63/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SPATA31D1 | c.869A>T p.D290V | Missense Mutation (SNP) | VAF 180/580 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); called by muse, varscan2
- SPRED2 | c.250del p.A84Pfs*32 | Frame Shift Del (DEL) | VAF 184/252 reads (73%) | called by mutect2, pindel*, varscan2*
- SPTB | c.5663T>A p.L1888Q | Missense Mutation (SNP) | VAF 243/668 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SQOR | c.1304G>T p.W435L | Missense Mutation (SNP) | VAF 80/304 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SRPK1 | c.463G>T p.G155* | Nonsense Mutation (SNP) | VAF 79/212 reads (37%) | called by muse, mutect2, varscan2
- SSC4D | c.941C>A p.P314Q | Missense Mutation (SNP) | VAF 89/258 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- STAB2 | c.6122G>A p.C2041Y | Missense Mutation (SNP) | VAF 57/164 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- STX11 | c.311_312del p.L104Pfs*11 | Frame Shift Del (DEL) | VAF 130/450 reads (29%) | called by mutect2, pindel, varscan2
- TACC2 | c.6845A>T p.N2282I (on ENST00000334433; = p.N360I on NM_006997.4) | Missense Mutation (SNP) | VAF 84/247 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.529); called by mutect2, varscan2
- TEK | c.2453T>A p.V818E | Missense Mutation (SNP) | VAF 198/308 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- TEX13C | c.1385G>A p.S462N | Missense Mutation (SNP) | VAF 228/336 reads (68%) | SIFT tolerated (0.16); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- THNSL1 | c.458A>T p.Y153F | Missense Mutation (SNP) | VAF 85/225 reads (38%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TM9SF3 | c.713del p.G238Afs*2 | Frame Shift Del (DEL) | VAF 38/152 reads (25%) | called by mutect2, pindel, varscan2
- TMCO3 | c.643G>C p.E215Q | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.729); called by mutect2, varscan2
- TNNI3K | c.1950C>A p.S650R | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TNRC6C | c.2479G>T p.V827L | Missense Mutation (SNP) | VAF 101/277 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2, varscan2
- TRGV3 | c.128T>G p.L43R | Missense Mutation (SNP) | VAF 362/657 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- TRIM60 | c.1312T>C p.Y438H | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT tolerated (0.22); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- TRIM77 | c.1194C>A p.H398Q | Missense Mutation (SNP) | VAF 50/294 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.009); called by mutect2, varscan2
- TYW1B | c.1174A>G p.M392V | Missense Mutation (SNP) | VAF 57/177 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); called by muse, mutect2, varscan2
- TYW5 | c.29G>T p.R10L | Missense Mutation (SNP) | VAF 141/205 reads (69%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- USH2A | c.10492G>T p.V3498L | Missense Mutation (SNP) | VAF 91/304 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- WDFY3 | c.4363C>T p.Q1455* | Nonsense Mutation (SNP) | VAF 15/32 reads (47%) | called by muse, mutect2, varscan2
- WDR86 | c.712del p.V238Sfs*7 | Frame Shift Del (DEL) | VAF 48/168 reads (29%) | called by pindel, varscan2
- WSB1 | c.962A>G p.H321R | Missense Mutation (SNP) | VAF 97/304 reads (32%) | SIFT tolerated (0.35); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- WWC1 | c.3250del p.E1084Nfs*20 | Frame Shift Del (DEL) | VAF 90/275 reads (33%) | called by mutect2, pindel, varscan2
- ZC3H4 | c.3782A>T p.Q1261L | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- ZFHX4 | c.2710T>C p.F904L | Missense Mutation (SNP) | VAF 81/231 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.225); called by muse, mutect2, varscan2
- ZNF169 | c.1480G>T p.A494S | Missense Mutation (SNP) | VAF 109/167 reads (65%) | SIFT tolerated (0.08); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZNF469 | c.10351A>C p.M3451L (on ENST00000437464; = p.M3479L on NM_001367624.2) | Missense Mutation (SNP) | VAF 50/80 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ZNF804B | c.1847C>A p.A616E | Missense Mutation (SNP) | VAF 83/239 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ZNF93 | c.1430G>C p.G477A | Missense Mutation (SNP) | VAF 143/261 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.974); called by muse, varscan2
- ZP4 | c.152C>A p.S51Y | Missense Mutation (SNP) | VAF 58/152 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- ZSWIM4 | c.2080C>G p.R694G | Missense Mutation (SNP) | VAF 91/170 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ZSWIM8 | c.4032C>G p.D1344E (on ENST00000605216 / NM_001242487.2; = p.D1349E on NM_015037.3) | Missense Mutation (SNP) | VAF 139/335 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ACTA1 | c.327G>A p.E109= | Silent (SNP) | VAF 302/603 reads (50%) | catalogued as rs1175339508, CM095280; called by muse, mutect2, varscan2
- ADAMTS4 | c.2130C>A p.T710= | Silent (SNP) | VAF 89/171 reads (52%) | called by muse, mutect2, varscan2
- AFAP1 | c.1347G>T p.L449= | Silent (SNP) | VAF 17/25 reads (68%) | catalogued as COSV61795671; called by muse, mutect2, varscan2
- ALLC | c.1026A>G p.Q342= | Silent (SNP) | VAF 108/304 reads (36%) | called by muse, mutect2, varscan2
- ANKRD33B | c.822G>A p.A274= | Silent (SNP) | VAF 181/490 reads (37%) | called by muse, mutect2, varscan2
- AOAH | c.30G>T p.V10= | Silent (SNP) | VAF 115/386 reads (30%) | called by muse, mutect2, varscan2
- ART5 | c.510G>A p.K170= | Silent (SNP) | VAF 62/185 reads (34%) | catalogued as rs1565028783; called by muse, mutect2, varscan2
- ATXN7L2 | c.1986C>T p.C662= | Silent (SNP) | VAF 99/276 reads (36%) | called by muse, varscan2
- B4GALNT1 | c.21C>A p.A7= | Silent (SNP) | VAF 29/71 reads (41%) | called by muse, mutect2, varscan2
- BET1L | c.205C>A p.R69= | Silent (SNP) | VAF 24/61 reads (39%) | called by mutect2, varscan2
- CACNA1H | c.3384C>G p.P1128= | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as rs1167623135; called by muse, mutect2, varscan2
- CACNA2D4 | c.1200C>A p.I400= | Silent (SNP) | VAF 61/197 reads (31%) | called by muse, mutect2, varscan2
- CCDC178 | c.541C>A p.R181= | Silent (SNP) | VAF 92/142 reads (65%) | called by muse, mutect2, varscan2
- CCDC185 | c.1467G>A p.R489= | Silent (SNP) | VAF 160/362 reads (44%) | catalogued as rs1171378459; called by muse, mutect2, varscan2
- CCNK | c.93G>A p.L31= | Silent (SNP) | VAF 93/248 reads (38%) | called by muse, mutect2, varscan2
- CFAP157 | c.499T>C p.L167= | Silent (SNP) | VAF 83/158 reads (53%) | catalogued as rs1442226325; called by muse, mutect2, varscan2
- CFAP46 | c.5523T>A p.A1841= | Silent (SNP) | VAF 141/447 reads (32%) | called by muse, mutect2, varscan2
- CNDP1 | c.246G>T p.A82= | Silent (SNP) | VAF 112/184 reads (61%) | catalogued as COSV100722440; called by muse, mutect2, varscan2
- COL6A6 | c.4233T>C p.F1411= | Silent (SNP) | VAF 134/337 reads (40%) | catalogued as rs1465254083; called by muse, mutect2, varscan2
- CPSF1 | c.2314C>A p.R772= | Silent (SNP) | VAF 17/36 reads (47%) | called by muse, mutect2, varscan2
- CXXC1 | c.1641G>C p.V547= | Silent (SNP) | VAF 88/149 reads (59%) | called by muse, mutect2, varscan2
- DLK1 | c.501C>T p.C167= | Silent (SNP) | VAF 70/203 reads (34%) | catalogued as rs772453703; called by muse, mutect2, varscan2
- DNAH10 | c.12786C>T p.G4262= (on ENST00000409039; = p.G4201= on NM_207437.3) | Silent (SNP) | VAF 118/300 reads (39%) | called by muse, mutect2, varscan2
- FAM20A | c.51G>C p.A17= | Silent (SNP) | VAF 195/480 reads (41%) | called by muse, mutect2, varscan2
- FGF21 | c.171A>C p.T57= | Silent (SNP) | VAF 138/233 reads (59%) | called by muse, mutect2, varscan2
- FLYWCH2 | c.270C>T p.A90= | Silent (SNP) | VAF 111/317 reads (35%) | called by muse, mutect2, varscan2
- FRY | c.8515C>T p.L2839= | Silent (SNP) | VAF 99/172 reads (58%) | called by muse, mutect2, varscan2
- GCOM1 | c.861A>T p.A287= | Silent (SNP) | VAF 54/147 reads (37%) | called by muse, mutect2, varscan2
- GOLGA8J | c.855C>G p.S285= | Silent (SNP) | VAF 14/16 reads (88%) | called by mutect2, varscan2
- GRIN2B | c.2313G>A p.G771= | Silent (SNP) | VAF 50/146 reads (34%) | catalogued as rs150554184; ClinVar: not provided; called by muse, mutect2, varscan2
- GSC | c.177G>T p.P59= | Silent (SNP) | VAF 83/183 reads (45%) | called by muse, mutect2, varscan2
- HCN1 | c.2550C>A p.I850= | Silent (SNP) | VAF 89/221 reads (40%) | catalogued as rs772068771, COSV57532195; called by muse, varscan2
- HCN1 | c.2382C>A p.P794= | Silent (SNP) | VAF 93/277 reads (34%) | called by muse, mutect2, varscan2
- HMGCL | c.747G>A p.L249= | Silent (SNP) | VAF 38/89 reads (43%) | called by muse, mutect2, varscan2
- IQCB1 | c.222G>A p.Q74= | Silent (SNP) | VAF 124/343 reads (36%) | catalogued as rs540671081, COSV60436984; called by muse, mutect2, varscan2
- ITGA8 | c.1962G>T p.S654= | Silent (SNP) | VAF 86/221 reads (39%) | catalogued as COSV65225668, COSV65226356; called by muse, mutect2, varscan2
- KALRN | c.1524G>A p.L508= | Silent (SNP) | VAF 127/445 reads (29%) | catalogued as rs1444521113, COSV53764471; called by muse, mutect2, varscan2
- KLHL32 | c.138G>T p.L46= | Silent (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- LHCGR | c.348C>A p.P116= | Silent (SNP) | VAF 219/321 reads (68%) | called by muse, mutect2, varscan2
- LILRB5 | c.1650C>A p.P550= (on ENST00000449561 / NM_001081442.3; = p.P549= on NM_006840.5) | Silent (SNP) | VAF 135/219 reads (62%) | catalogued as COSV60258007; called by muse, mutect2, varscan2
- LPA | c.6024T>C p.T2008= | Silent (SNP) | VAF 252/682 reads (37%) | called by muse, mutect2, varscan2
- LRIG3 | c.363A>C p.A121= | Silent (SNP) | VAF 66/187 reads (35%) | called by muse, mutect2, varscan2
- LZTS2 | c.1719C>T p.A573= | Silent (SNP) | VAF 14/44 reads (32%) | called by muse, mutect2, varscan2
- MADD | c.3840G>A p.Q1280= | Silent (SNP) | VAF 71/238 reads (30%) | called by muse, mutect2, varscan2
- MAGEL2 | c.63T>A p.P21= | Silent (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2
- MAP3K21 | c.2196G>T p.S732= | Silent (SNP) | VAF 199/399 reads (50%) | catalogued as COSV64041529; called by muse, mutect2, varscan2
- MARVELD1 | c.519G>T p.A173= | Silent (SNP) | VAF 50/125 reads (40%) | called by muse, mutect2, varscan2
- MBP | c.129C>T p.N43= | Silent (SNP) | VAF 69/156 reads (44%) | catalogued as rs760137415; called by muse, mutect2, varscan2
- MC1R | c.522C>T p.V174= | Silent (SNP) | VAF 113/184 reads (61%) | called by muse, mutect2, varscan2
- MRGPRX1 | c.534C>T p.F178= | Silent (SNP) | VAF 166/465 reads (36%) | catalogued as COSV100245937; called by muse, mutect2, varscan2
- MROH2B | c.3903G>A p.L1301= | Silent (SNP) | VAF 88/244 reads (36%) | called by muse, mutect2, varscan2
- NLRP3 | c.1293C>T p.A431= | Silent (SNP) | VAF 188/392 reads (48%) | catalogued as rs764901109, COSV60232012; called by muse, mutect2
- OR10X1 | c.303A>G p.L101= | Silent (SNP) | VAF 118/426 reads (28%) | called by muse, mutect2, varscan2
- OR11H2 | c.171G>T p.R57= (on ENST00000556246; = p.R68= on NM_001197287.1) | Silent (SNP) | VAF 140/425 reads (33%) | called by muse, mutect2, varscan2
- OR4A16 | c.274T>C p.L92= | Silent (SNP) | VAF 121/339 reads (36%) | catalogued as COSV100125435; called by muse, mutect2, varscan2
- OR4C12 | c.789G>T p.L263= | Silent (SNP) | VAF 63/175 reads (36%) | catalogued as rs1555020052; called by muse, mutect2, varscan2
- OR4K2 | c.492C>T p.L164= | Silent (SNP) | VAF 78/264 reads (30%) | catalogued as COSV53849428; called by muse, mutect2, varscan2
- OR5I1 | c.858G>T p.V286= | Silent (SNP) | VAF 34/114 reads (30%) | called by muse, mutect2, varscan2
- PADI3 | c.1548G>T p.G516= | Silent (SNP) | VAF 98/155 reads (63%) | called by muse, mutect2, varscan2
- PCDHB13 | c.1227A>T p.L409= | Silent (SNP) | VAF 141/340 reads (41%) | called by muse, mutect2, varscan2
- PCDHB7 | c.2175G>C p.V725= | Silent (SNP) | VAF 170/430 reads (40%) | catalogued as rs1210797298; called by muse, mutect2, varscan2
- PCDHGA9 | c.897G>A p.G299= | Silent (SNP) | VAF 60/160 reads (38%) | called by mutect2, varscan2
- PCDHGB3 | c.2376C>T p.D792= | Silent (SNP) | VAF 44/144 reads (31%) | called by mutect2, varscan2
- PEG3 | c.789C>T p.D263= | Silent (SNP) | VAF 101/171 reads (59%) | catalogued as rs142177720, COSV55627105; called by muse, mutect2, varscan2
- PLEKHG5 | c.1074G>T p.R358= (on ENST00000400915 / NM_001042663.3; = p.R321= on NM_020631.6) | Silent (SNP) | VAF 248/388 reads (64%) | called by muse, mutect2, varscan2
- PROZ | c.879C>T p.I293= | Silent (SNP) | VAF 119/163 reads (73%) | called by muse, mutect2, varscan2
- PSG3 | c.54C>T p.L18= | Silent (SNP) | VAF 169/319 reads (53%) | called by muse, mutect2, varscan2
- PSKH2 | c.417G>T p.L139= | Silent (SNP) | VAF 115/328 reads (35%) | called by muse, mutect2, varscan2
- PTPRD | c.4896G>A p.L1632= | Silent (SNP) | VAF 68/118 reads (58%) | catalogued as rs1348180736; called by muse, mutect2, varscan2
- PTPRJ | c.3738G>T p.T1246= | Silent (SNP) | VAF 58/156 reads (37%) | catalogued as COSV101395041; called by muse, mutect2, varscan2
- RASGEF1A | c.6C>T p.P2= | Silent (SNP) | VAF 68/201 reads (34%) | catalogued as rs764502177; called by muse, mutect2, varscan2
- RIPK1 | c.1566G>A p.L522= | Silent (SNP) | VAF 23/68 reads (34%) | called by muse, mutect2, varscan2
- RNF133 | c.234A>T p.P78= | Silent (SNP) | VAF 55/160 reads (34%) | called by muse, mutect2, varscan2
- RP1L1 | c.5862C>A p.T1954= | Silent (SNP) | VAF 170/274 reads (62%) | called by mutect2, varscan2
- RPUSD2 | c.801A>G p.L267= | Silent (SNP) | VAF 157/437 reads (36%) | called by muse, mutect2, varscan2
- SAC3D1 | c.138T>C p.D46= | Silent (SNP) | VAF 520/713 reads (73%) | catalogued as rs891356991; called by muse, mutect2, varscan2
- SCNN1B | c.1065G>T p.G355= | Silent (SNP) | VAF 102/314 reads (32%) | called by muse, mutect2, varscan2
- SENP7 | c.2307T>C p.C769= | Silent (SNP) | VAF 66/193 reads (34%) | called by muse, mutect2, varscan2
- SIGLEC5 | c.579C>A p.T193= | Silent (SNP) | VAF 128/243 reads (53%) | called by muse, mutect2, varscan2
- SLC52A2 | c.768G>A p.Q256= | Silent (SNP) | VAF 131/344 reads (38%) | called by muse, mutect2, varscan2
- SLC6A3 | c.831C>T p.L277= | Silent (SNP) | VAF 331/866 reads (38%) | catalogued as rs767453645; called by muse, mutect2, varscan2
- SLCO2B1 | c.687C>A p.I229= | Silent (SNP) | VAF 46/225 reads (20%) | catalogued as COSV56936869; called by muse, mutect2, varscan2
- SLCO6A1 | c.726A>T p.A242= | Silent (SNP) | VAF 67/113 reads (59%) | called by muse, mutect2, varscan2
- SPTBN4 | c.3336C>A p.G1112= | Silent (SNP) | VAF 34/50 reads (68%) | catalogued as rs1374190713; called by muse, mutect2, varscan2
- TDRD1 | c.1455A>T p.P485= | Silent (SNP) | VAF 43/104 reads (41%) | called by muse, mutect2, varscan2
- TGFBR1 | c.558G>T p.T186= | Silent (SNP) | VAF 97/156 reads (62%) | catalogued as rs538382054; called by muse, mutect2, varscan2
- THBS2 | c.1944C>A p.P648= | Silent (SNP) | VAF 95/226 reads (42%) | called by muse, mutect2, varscan2
- TLE2 | c.714G>A p.V238= | Silent (SNP) | VAF 17/24 reads (71%) | catalogued as rs1022264257; called by muse, mutect2, varscan2
- TOP1MT | c.387C>T p.V129= | Silent (SNP) | VAF 85/246 reads (35%) | called by muse, mutect2, varscan2
- TPBGL | c.174C>T p.P58= | Silent (SNP) | VAF 111/562 reads (20%) | called by muse, mutect2, varscan2
- TRAV8-3 | c.177C>A p.P59= | Silent (SNP) | VAF 165/284 reads (58%) | called by muse, mutect2, varscan2
- USF3 | c.5367A>G p.Q1789= | Silent (SNP) | VAF 93/254 reads (37%) | catalogued as rs1369643311; called by muse, mutect2, varscan2
- USP47 | c.33G>A p.P11= | Silent (SNP) | VAF 66/228 reads (29%) | catalogued as rs1221099217; called by muse, mutect2, varscan2
- VAV2 | c.2196A>G p.T732= (on ENST00000371850 / NM_001134398.2; = p.T722= on NM_003371.4) | Silent (SNP) | VAF 69/127 reads (54%) | called by muse, mutect2, varscan2
- WDR4 | c.1179G>T p.P393= | Silent (SNP) | VAF 144/335 reads (43%) | catalogued as COSV100375438, COSV57734516; called by muse, mutect2
- WDR74 | c.159C>T p.G53= | Silent (SNP) | VAF 124/346 reads (36%) | catalogued as rs111846457; called by muse, varscan2
- WDR86 | c.694C>A p.R232= | Silent (SNP) | VAF 76/182 reads (42%) | catalogued as rs201973356; called by muse, varscan2
- XRCC6 | c.903G>T p.R301= | Silent (SNP) | VAF 71/125 reads (57%) | called by muse, mutect2, varscan2
- ZNF574 | c.1113G>T p.L371= | Silent (SNP) | VAF 146/217 reads (67%) | called by muse, mutect2, varscan2
- ZNF609 | c.2325T>C p.N775= | Silent (SNP) | VAF 82/188 reads (44%) | called by muse, mutect2, varscan2
- ABCC8 | c.1333-12C>G | Intron (SNP) | VAF 138/362 reads (38%) | called by muse, mutect2, varscan2
- AC023469.1 | n.352C>A | RNA (SNP) | VAF 120/157 reads (76%) | called by muse, mutect2, varscan2
- AC079612.1 | n.509G>T | RNA (SNP) | VAF 313/417 reads (75%) | called by muse, mutect2, varscan2
- AC104078.1 | n.285G>C | RNA (SNP) | VAF 105/256 reads (41%) | called by muse, mutect2, varscan2
- AC136759.1 | n.537C>A | RNA (SNP) | VAF 131/386 reads (34%) | called by muse, mutect2, varscan2
- AC136759.1 | n.1478G>T | RNA (SNP) | VAF 176/483 reads (36%) | called by muse, mutect2, varscan2
- ACTN1 | c.2361+511A>G | Intron (SNP) | VAF 15/34 reads (44%) | called by muse, mutect2, varscan2
- ADAM1A | n.1128C>T | RNA (SNP) | VAF 147/333 reads (44%) | called by muse, mutect2, varscan2
- ADAM21P1 | n.894C>G | RNA (SNP) | VAF 170/423 reads (40%) | called by muse, mutect2, varscan2
- AL035696.1 | n.459T>A | RNA (SNP) | VAF 34/87 reads (39%) | called by muse, mutect2, varscan2
- AL627230.3 | c.76-106G>C | Intron (SNP) | VAF 124/584 reads (21%) | catalogued as rs1416910199; called by mutect2, varscan2
- ANKIB1 | c.-180A>T | 5'UTR (SNP) | VAF 155/418 reads (37%) | called by muse, mutect2, varscan2
- ANO1 | c.-44G>T | 5'UTR (SNP) | VAF 252/371 reads (68%) | called by muse, varscan2
- ARMCX4 | c.1039-3077T>G | Intron (SNP) | VAF 114/144 reads (79%) | called by muse, mutect2, varscan2
- ATXN2 | c.2998+21G>A | Intron (SNP) | VAF 25/53 reads (47%) | called by muse, mutect2, varscan2
- BNIP2 | chr15:59689398 G>C | 5'Flank (SNP) | VAF 64/184 reads (35%) | called by mutect2, varscan2
- BRF1 | c.*1059A>C | 3'UTR (SNP) | VAF 98/267 reads (37%) | called by muse, mutect2, varscan2
- CCDC89 | chr11:85682864 G>A | 3'Flank (SNP) | VAF 134/709 reads (19%) | catalogued as rs892356552; called by muse, mutect2, varscan2
- CD163L1 | c.445+17A>T | Intron (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2
- CHCHD3 | c.170-10243A>T | Intron (SNP) | VAF 277/722 reads (38%) | called by muse, mutect2, varscan2
- CLASP2 | c.1927+347C>G | Intron (SNP) | VAF 84/126 reads (67%) | catalogued as rs1286729920; called by muse, mutect2, varscan2
- CORO6 | c.754-123T>C | Intron (SNP) | VAF 19/72 reads (26%) | called by muse, mutect2, varscan2
- DNAH14 | c.2938+1876T>C | Intron (SNP) | VAF 120/385 reads (31%) | called by muse, mutect2, varscan2
- DNAH14 | c.9206-2438A>T | Intron (SNP) | VAF 138/327 reads (42%) | called by muse, mutect2, varscan2
- FAAP100 | c.1404-25dup | Intron (INS) | VAF 32/98 reads (33%) | called by mutect2, pindel, varscan2
- FCGR2C | c.795+69C>A | Intron (SNP) | VAF 159/396 reads (40%) | called by muse, mutect2, varscan2
- FOLH1B | n.1700G>T | RNA (SNP) | VAF 98/613 reads (16%) | catalogued as rs375829835; called by muse, mutect2, varscan2
- FUS | c.190+126C>G | Intron (SNP) | VAF 32/71 reads (45%) | called by muse, mutect2, varscan2
- GLI3 | c.125-24075G>T | Intron (SNP) | VAF 93/146 reads (64%) | catalogued as rs1480469803, COSV101229948; called by muse, mutect2, varscan2
- IGHM | c.1300+38C>A | Intron (SNP) | VAF 225/606 reads (37%) | called by muse, mutect2, varscan2
- IGLV8OR8-1 | n.313C>T | RNA (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2, varscan2
- INTS8 | chr8:94823237 G>T | 5'Flank (SNP) | VAF 33/108 reads (31%) | called by muse, mutect2, varscan2
- LILRB5 | c.1306+68G>T | Intron (SNP) | VAF 20/32 reads (63%) | called by muse, mutect2, varscan2
- LINC00868 | n.976A>T | RNA (SNP) | VAF 71/189 reads (38%) | called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85804G>C | Intron (SNP) | VAF 159/320 reads (50%) | called by muse, mutect2, varscan2
- MAX | c.295+307G>T | Intron (SNP) | VAF 46/102 reads (45%) | called by muse, mutect2
- MAX | c.295+305A>T | Intron (SNP) | VAF 44/101 reads (44%) | called by muse, mutect2
- MDGA2 | c.2752+1496G>C | Intron (SNP) | VAF 47/84 reads (56%) | called by muse, mutect2, varscan2
- MEGF11 | c.2215+64T>G | Intron (SNP) | VAF 45/126 reads (36%) | called by muse, mutect2, varscan2
- MLXIPL | c.1823-42C>A | Intron (SNP) | VAF 155/393 reads (39%) | called by muse, mutect2, varscan2
- MMAB | c.*351G>C | 3'UTR (SNP) | VAF 31/278 reads (11%) | called by muse, varscan2
- MMAB | c.*347G>C | 3'UTR (SNP) | VAF 73/277 reads (26%) | called by muse, varscan2
- MUC20P1 | n.1120A>G | RNA (SNP) | VAF 210/1732 reads (12%) | catalogued as rs749419532; called by muse, varscan2
- MYH16 | n.4197C>A | RNA (SNP) | VAF 47/130 reads (36%) | called by muse, mutect2, varscan2
- MYL6 | c.428-44G>T | Intron (SNP) | VAF 130/408 reads (32%) | called by muse, mutect2
- MYL6 | c.428-42C>T | Intron (SNP) | VAF 128/402 reads (32%) | catalogued as COSV99255268; called by muse, mutect2
- NACA | c.70+3601G>T | Intron (SNP) | VAF 79/232 reads (34%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.1748G>T | RNA (SNP) | VAF 225/293 reads (77%) | called by muse, mutect2, varscan2
- NPAT | c.-42_-22del | 5'UTR (DEL) | VAF 96/241 reads (40%) | called by mutect2, pindel, varscan2
- NTRK3 | c.2133+16C>A | Intron (SNP) | VAF 138/396 reads (35%) | called by muse, mutect2, varscan2
- OCEL1 | chr19:17226219 C>T | 5'Flank (SNP) | VAF 156/228 reads (68%) | called by muse, mutect2, varscan2
- OFCC1 | n.1060C>A | RNA (SNP) | VAF 84/234 reads (36%) | called by muse, mutect2, varscan2
- OR6W1P | n.399C>G | RNA (SNP) | VAF 72/209 reads (34%) | called by muse, mutect2, varscan2
- OVCH1-AS1 | n.298C>G | RNA (SNP) | VAF 56/203 reads (28%) | called by muse, mutect2, varscan2
- PRDM11 | c.657-6070G>T | Intron (SNP) | VAF 106/226 reads (47%) | called by muse, mutect2, varscan2
- PRDM11 | chr11:45227413 C>T | 3'Flank (SNP) | VAF 131/303 reads (43%) | catalogued as rs1457161354; called by muse, mutect2, varscan2
- PRPF31 | c.238+14C>G | Intron (SNP) | VAF 66/109 reads (61%) | called by muse, mutect2, varscan2
- PTPN20 | c.-12del | 5'UTR (DEL) | VAF 138/591 reads (23%) | called by mutect2, varscan2
- PYHIN1 | c.579+269G>C | Intron (SNP) | VAF 102/236 reads (43%) | called by muse, varscan2
- RAB26 | c.*196G>T | 3'UTR (SNP) | VAF 30/68 reads (44%) | called by muse, mutect2, varscan2
- RAD51D | c.576+135A>T | Intron (SNP) | VAF 137/379 reads (36%) | called by muse, mutect2, varscan2
- SLC6A10P | n.3721C>G | RNA (SNP) | VAF 72/202 reads (36%) | called by mutect2, varscan2
- SNORD115-21 | n.81del | RNA (DEL) | VAF 142/446 reads (32%) | called by mutect2, pindel, varscan2
- SPATS2 | c.-34T>C | 5'UTR (SNP) | VAF 64/169 reads (38%) | called by muse, mutect2, varscan2
- SSPOP | n.972C>T | RNA (SNP) | VAF 34/105 reads (32%) | called by muse, mutect2, varscan2
- SSPOP | n.2787G>T | RNA (SNP) | VAF 71/136 reads (52%) | called by muse, mutect2, varscan2
- SSPOP | n.14414G>T | RNA (SNP) | VAF 117/363 reads (32%) | catalogued as COSV65137921; called by muse, mutect2, varscan2
- STIM2 | c.1763+1504A>T | Intron (SNP) | VAF 94/230 reads (41%) | called by muse, mutect2, varscan2
- TBXT | c.-15G>T | 5'UTR (SNP) | VAF 167/415 reads (40%) | called by muse, mutect2, varscan2
- TCTN2 | c.1312+40A>T | Intron (SNP) | VAF 51/138 reads (37%) | called by muse, mutect2, varscan2
- TM6SF2 | c.401+130C>T | Intron (SNP) | VAF 26/44 reads (59%) | called by muse, mutect2, varscan2
- TRDN | c.-37G>T | 5'UTR (SNP) | VAF 56/166 reads (34%) | called by muse, mutect2, varscan2
- TTC41P | n.331G>T | RNA (SNP) | VAF 82/180 reads (46%) | called by muse, mutect2, varscan2
- TXLNGY | chrY:19587588 G>C | 5'Flank (SNP) | VAF 177/231 reads (77%) | called by muse, mutect2, varscan2
- WSCD1 | c.-2G>A | 5'UTR (SNP) | VAF 129/199 reads (65%) | catalogued as rs772153163; called by muse, mutect2, varscan2
- WWTR1 | c.771+1288A>G | Intron (SNP) | VAF 53/171 reads (31%) | called by muse, mutect2, varscan2
- XIST | n.10883G>T | RNA (SNP) | VAF 82/106 reads (77%) | called by muse, mutect2, varscan2
- ZNF252P | n.245+4184T>A | Intron (SNP) | VAF 82/234 reads (35%) | called by muse, mutect2, varscan2
- ZNF705A | c.-2C>A | 5'UTR (SNP) | VAF 94/309 reads (30%) | called by muse, mutect2, varscan2
- ZNF99 | c.*3118C>T | 3'UTR (SNP) | VAF 37/64 reads (58%) | catalogued as rs187603626; called by muse, mutect2, varscan2
- ZNRF2 | c.-332G>T | 5'UTR (SNP) | VAF 133/501 reads (27%) | called by muse, mutect2, varscan2
- ZSCAN1 | c.370+149T>C | Intron (SNP) | VAF 16/27 reads (59%) | called by muse, mutect2, varscan2
